Somatic mutation profile of tumor specimen TCGA-AA-3955-01A (aliquot TCGA-AA-3955-01A-02W-0995-10) from TCGA case TCGA-AA-3955, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 38.8 years (14,186 days).
Specimen TCGA-AA-3955-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e28d791d-5838-4615-9b00-81d08199b71e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-3955-10A (Blood Derived Normal), aliquot TCGA-AA-3955-10A-01W-0995-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f417694f-5c8d-4e5e-8cc8-862210cd7d9e

The open-access MAF lists 142 somatic variants for this specimen: 107 protein-altering or splice-affecting, 31 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 85, Silent 31, Nonsense Mutation 11, Intron 4, Frame Shift Del 4, Frame Shift Ins 3, Splice Site 2, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.867_873del p.R290Kfs*53 | Frame Shift Del (DEL) | VAF 69/120 reads (58%) | hotspot (GDC flag); catalogued as COSV53760429; called by mutect2, pindel, varscan2
- TTN | c.5047C>T p.R1683* (on ENST00000591111; = p.R1637* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 4/12 reads (33%) | catalogued as rs587780490, COSV59948489; ClinVar: uncertain significance / pathogenic; called by muse, varscan2
- ABCB8 | c.550G>A p.V184I (on ENST00000297504 / NM_001282291.2; = p.V167I on NM_007188.5) | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.164); catalogued as rs771656314, COSV52509560; called by muse, mutect2, varscan2
- ABCC4 | c.2831C>T p.T944M | Missense Mutation (SNP) | VAF 42/83 reads (51%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.719); catalogued as rs750954023, COSV65311373; called by muse, mutect2, varscan2
- ACOT8 | c.226C>T p.H76Y | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs1435606753, COSV99467218; called by muse, mutect2, varscan2
- ADAMTS16 | c.2276A>T p.N759I | Missense Mutation (SNP) | VAF 41/166 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV56997474, COSV99939882; called by muse, mutect2, varscan2
- ADGRV1 | c.12584C>T p.P4195L | Missense Mutation (SNP) | VAF 148/626 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs1396728514, COSV101315410; called by muse, varscan2
- ALDH3B2 | c.30+2T>G p.X10_splice | Splice Site (SNP) | VAF 20/66 reads (30%) | catalogued as rs1293315587, COSV100823956; called by muse, mutect2, varscan2
- APC | c.4148dup p.M1383Ifs*3 | Frame Shift Ins (INS) | VAF 53/104 reads (51%) | catalogued as COSV57323145; called by mutect2, pindel, varscan2
- BOD1L1 | c.1152A>T p.K384N | Missense Mutation (SNP) | VAF 53/238 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.184); catalogued as COSV99238271; called by muse, mutect2, varscan2
- CC2D2A | c.1508G>C p.R503T | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV101052650; called by muse, mutect2
- CDK15 | c.236G>A p.C79Y (on ENST00000652192 / NM_001366386.2; = p.C28Y on NM_139158.2) | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV53639581; called by muse, mutect2, varscan2
- CELA1 | c.217G>C p.V73L | Missense Mutation (SNP) | VAF 37/66 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99529931; called by muse, mutect2, varscan2
- CEMIP | c.3340T>G p.L1114V | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.51); PolyPhen benign (0.01); catalogued as COSV99585949; called by muse, mutect2, varscan2
- CEP162 | c.524T>G p.L175R | Missense Mutation (SNP) | VAF 37/224 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV100002336; called by muse, mutect2, varscan2
- CLIC6 | c.2109G>T p.M703I (on ENST00000360731 / NM_001317009.2; = p.M685I on NM_053277.3) | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.066); catalogued as COSV62447384, COSV62449978; called by muse, mutect2, varscan2
- CNTNAP1 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99226091; called by muse, mutect2, varscan2
- COL22A1 | c.253C>T p.R85W | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs139591204; called by muse, mutect2, varscan2
- COL5A3 | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 44/1799 reads (2%) | SIFT tolerated (0.62); PolyPhen benign (0.024); catalogued as COSV99318150; called by muse, mutect2
- COLGALT1 | c.959C>T p.P320L | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.706); catalogued as rs780399866, COSV53111968, COSV99394891; called by muse, mutect2, varscan2
- DMD | c.3130G>C p.E1044Q | Missense Mutation (SNP) | VAF 89/190 reads (47%) | SIFT tolerated (0.45); PolyPhen benign (0.187); catalogued as COSV100821731, COSV63732339; called by muse, mutect2, varscan2
- DNAH5 | c.4687G>A p.G1563S | Missense Mutation (SNP) | VAF 432/886 reads (49%) | SIFT tolerated (0.67); PolyPhen benign (0.001); catalogued as rs147567352; ClinVar: likely benign / uncertain significance; called by muse, varscan2
- DNER | c.1062G>C p.Q354H | Missense Mutation (SNP) | VAF 23/499 reads (5%) | SIFT tolerated (0.77); PolyPhen benign (0.018); catalogued as COSV100518210, COSV59159922; called by muse, mutect2
- DPP10 | c.1648T>C p.S550P | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.837); catalogued as COSV59740807; called by muse, mutect2, varscan2
- EEF2 | c.216A>T p.S72= | Splice Region (SNP) | VAF 24/74 reads (32%) | catalogued as COSV58581229; called by muse, mutect2, varscan2
- ELAVL4 | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs1345370346, COSV63914597; called by muse, mutect2, varscan2
- ERICH6 | c.1759del p.R587Dfs*3 | Frame Shift Del (DEL) | VAF 19/87 reads (22%) | catalogued as COSV99901956; called by mutect2, pindel, varscan2
- ERN2 | c.1964G>A p.R655K | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.557); catalogued as COSV99890488; called by muse, mutect2
- ESRRG | c.167A>T p.H56L | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.055); catalogued as COSV100752202, COSV63156032; called by muse, mutect2
- F5 | c.851C>G p.S284* | Nonsense Mutation (SNP) | VAF 71/357 reads (20%) | catalogued as COSV100888851; called by muse, mutect2, varscan2
- FNDC1 | c.1389G>T p.E463D | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV99794772; called by muse, mutect2
- FSIP1 | c.430C>G p.L144V | Missense Mutation (SNP) | VAF 113/381 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.096); catalogued as COSV63227479; called by muse, mutect2, varscan2
- GGA2 | c.757C>G p.R253G | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.477); catalogued as COSV59168862, COSV59170917; called by muse, mutect2, varscan2
- GJA5 | c.527G>C p.G176A | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54787119; called by muse, mutect2, varscan2
- GRB7 | c.925C>T p.R309* | Nonsense Mutation (SNP) | VAF 9/18 reads (50%) | catalogued as rs1203400544, COSV100485351; called by muse, mutect2, varscan2
- GTPBP4 | c.973G>T p.E325* | Nonsense Mutation (SNP) | VAF 12/206 reads (6%) | catalogued as COSV100672369; called by muse, mutect2
- IL18R1 | c.499A>G p.K167E | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.66); PolyPhen benign (0.043); catalogued as COSV99294846; called by muse, mutect2, varscan2
- INSC | c.276T>G p.C92W | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV101088710; called by muse, mutect2, varscan2
- ITGA2B | c.1283A>G p.E428G | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.005); catalogued as rs1392243083; called by muse, mutect2
- JAKMIP2 | c.925C>T p.R309* | Nonsense Mutation (SNP) | VAF 34/153 reads (22%) | catalogued as rs971625927, COSV54603438; called by muse, mutect2, varscan2
- KCNC2 | c.1233C>A p.N411K | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.171); catalogued as COSV100128147, COSV54373983; called by muse, mutect2, varscan2
- KLHL5 | c.1326G>T p.M442I | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.157); catalogued as COSV99784715; called by muse, mutect2, varscan2
- KYAT3 | c.1027C>G p.P343A | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.153); catalogued as COSV53106682; called by muse, mutect2, varscan2
- LILRA5 | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT tolerated (0.56); PolyPhen benign (0.011); catalogued as rs146444616; called by muse, mutect2, varscan2
- LTBP4 | c.2635G>A p.V879M (on ENST00000308370 / NM_001042544.1; = p.V842M on NM_003573.2) | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as rs764548567, COSV52592672; called by muse, mutect2, varscan2
- MAGEC1 | c.1691T>G p.F564C | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.549); catalogued as COSV99594753; called by muse, mutect2, varscan2
- MAGT1 | c.990C>A p.Y330* (on ENST00000618282 / NM_001367916.1; = p.Y362* on NM_032121.5) | Nonsense Mutation (SNP) | VAF 11/32 reads (34%) | catalogued as COSV63783362; called by muse, mutect2, varscan2
- MAN1A1 | c.775G>C p.E259Q | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.489); catalogued as COSV63785030; called by muse, mutect2, varscan2
- MRGPRX1 | c.698G>C p.G233A | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV100245827; called by muse, mutect2, varscan2
- MUC16 | c.8875A>T p.T2959S | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.801); catalogued as COSV101197890; called by muse, mutect2, varscan2
- MYBPC3 | c.3673G>T p.A1225S | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV57025912; called by muse, mutect2, varscan2
- MYO5A | c.5308A>T p.M1770L | Missense Mutation (SNP) | VAF 77/135 reads (57%) | SIFT tolerated (0.81); PolyPhen benign (0.015); catalogued as COSV100697252; called by muse, mutect2, varscan2
- NDUFAF4 | c.247G>C p.A83P | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.212); catalogued as COSV100293989; called by muse, mutect2, varscan2
- NIN | c.1355G>A p.R452H | Missense Mutation (SNP) | VAF 150/667 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.156); catalogued as rs182667346, COSV99811375; called by muse, mutect2, varscan2
- NME6 | c.287G>C p.R96T (on ENST00000415053; = p.R104T on NM_005793.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100189330; called by muse, mutect2, varscan2
- NRXN1 | c.3181C>T p.R1061W | Missense Mutation (SNP) | VAF 62/204 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765632172, COSV58471239; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NSL1 | c.566A>C p.K189T | Missense Mutation (SNP) | VAF 105/407 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV65330413; called by muse, mutect2, varscan2
- NUP188 | c.1817C>A p.P606Q | Missense Mutation (SNP) | VAF 109/326 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV101001161; called by muse, mutect2, varscan2
- OR2T2 | c.818A>T p.K273I | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100737541; called by muse, mutect2, varscan2
- OR51Q1 | c.800C>A p.A267D | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV56180867; called by muse, mutect2, varscan2
- OR52E6 | c.747C>G p.I249M | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.609); catalogued as COSV61433801; called by muse, mutect2, varscan2
- OR5R1 | c.954A>T p.L318F | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.021); catalogued as rs141438285; called by muse, mutect2, varscan2
- OTOL1 | c.32T>G p.L11* | Nonsense Mutation (SNP) | VAF 17/43 reads (40%) | catalogued as COSV100019717; called by muse, mutect2, varscan2
- OXCT1 | c.1254G>C p.K418N | Missense Mutation (SNP) | VAF 33/161 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52167602, COSV99541629; called by muse, mutect2, varscan2
- PLCE1 | c.1867G>A p.E623K | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.761); catalogued as rs1471710477, COSV99593228; called by muse, mutect2, varscan2
- PLCL2 | c.1483G>C p.V495L (on ENST00000615277 / NM_001144382.2; = p.V369L on NM_015184.5) | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV101196543; called by muse, mutect2, varscan2
- PLK1 | c.505C>T p.R169* | Nonsense Mutation (SNP) | VAF 59/213 reads (28%) | catalogued as COSV55622568; called by muse, mutect2, varscan2
- POLR3D | c.447A>T p.E149D | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.118); catalogued as COSV60572268; called by muse, mutect2, varscan2
- POU2F2 | c.1138C>T p.P380S (on ENST00000526816 / NM_001207025.3; = p.P364S on NM_002698.5) | Missense Mutation (SNP) | VAF 79/344 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as rs1315959841, COSV100657194; called by muse, mutect2, varscan2
- PREP | c.1832A>T p.K611M (on ENST00000369110; = p.K677M on NM_002726.5) | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV64872701; called by muse, mutect2, varscan2
- PRLR | c.572T>G p.F191C | Missense Mutation (SNP) | VAF 73/334 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV99184196; called by muse, mutect2, varscan2
- PRPF4B | c.1445G>T p.R482L | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.931); catalogued as COSV100527966; called by muse, mutect2, varscan2
- PTPN13 | c.820C>A p.P274T | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT tolerated (0.11); PolyPhen benign (0.075); catalogued as COSV100363937; called by muse, mutect2, varscan2
- RAD52 | c.593C>T p.P198L | Missense Mutation (SNP) | VAF 44/318 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs1391132880, COSV57274926; called by muse, mutect2, varscan2
- RIOK3 | c.341A>T p.E114V | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.298); catalogued as COSV59775549; called by muse, mutect2, varscan2
- RMC1 | c.226A>T p.N76Y | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.289); catalogued as COSV52575309; called by muse, mutect2, varscan2
- RNF19B | c.1547T>G p.F516C | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.72); catalogued as COSV99331131; called by muse, mutect2, varscan2
- ROCK2 | c.2847G>T p.E949D | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.788); catalogued as rs923187286, COSV59966921; called by muse, mutect2, varscan2
- RTN3 | c.3089dup p.A1031Gfs*28 (on ENST00000377819 / NM_001265589.2; = p.A235Gfs*28 on NM_006054.4) | Frame Shift Ins (INS) | VAF 16/42 reads (38%) | catalogued as rs747510098; called by mutect2, varscan2
- SLC22A15 | c.806C>G p.A269G | Missense Mutation (SNP) | VAF 62/239 reads (26%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.666); catalogued as rs754520667, COSV65679238; called by muse, mutect2, varscan2
- SLC25A13 | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as rs771117913, COSV55703524, COSV55706553; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC7A11 | c.649C>T p.Q217* | Nonsense Mutation (SNP) | VAF 12/192 reads (6%) | catalogued as COSV99762884; called by muse, mutect2
- SPAG17 | c.2632A>G p.I878V | Missense Mutation (SNP) | VAF 61/311 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as rs771554280, COSV100307754; called by muse, mutect2, varscan2
- SPI1 | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0.21); catalogued as rs1436543048, COSV57047541, COSV99908638; called by muse, mutect2, varscan2
- TM2D2 | c.343G>C p.E115Q (on ENST00000456397 / NM_078473.3; = p.E72Q on NM_031940.4) | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs1286544839, COSV56761593; called by muse, mutect2, varscan2
- TMEM141 | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV51567782; called by muse, mutect2
- TMIGD3 | c.374C>T p.T125I (on ENST00000369717 / NM_001081976.2; = p.T206I on NM_020683.7) | Missense Mutation (SNP) | VAF 113/408 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as rs746708794, COSV63163894; called by muse, mutect2, varscan2
- TPH2 | c.992A>T p.K331M | Missense Mutation (SNP) | VAF 50/164 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.409); catalogued as COSV61590489, COSV61591680, COSV61594179; called by muse, mutect2, varscan2
- TRIM3 | c.916C>T p.R306W | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV61984622; called by muse, mutect2, varscan2
- TRPA1 | c.2045C>T p.P682L | Missense Mutation (SNP) | VAF 91/332 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201119954, COSV51555022; called by muse, mutect2, varscan2
- TTC32 | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 58/212 reads (27%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.741); catalogued as rs748980235, COSV61268203; called by muse, mutect2, varscan2
- TTI1 | c.2783G>C p.R928T | Missense Mutation (SNP) | VAF 15/146 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV100989557; called by muse, mutect2, varscan2
- TUB | c.1051C>T p.Q351* (on ENST00000299506 / NM_177972.3; = p.Q406* on NM_003320.4) | Nonsense Mutation (SNP) | VAF 29/176 reads (16%) | catalogued as COSV100210004; called by muse, mutect2, varscan2
- USP31 | c.1286A>G p.H429R | Missense Mutation (SNP) | VAF 85/437 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.023); catalogued as rs1417691687, COSV99564542; called by muse, mutect2, varscan2
- USP34 | c.6445G>A p.D2149N | Missense Mutation (SNP) | VAF 33/219 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.534); catalogued as COSV101276600; called by muse, mutect2, varscan2
- UST | c.380A>G p.E127G | Missense Mutation (SNP) | VAF 40/264 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.055); catalogued as COSV100819752, COSV66548782; called by muse, varscan2
- VPS13C | c.10345G>C p.V3449L (on ENST00000644861 / NM_020821.3; = p.V3406L on NM_017684.5) | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV51429607; called by muse, mutect2, varscan2
- VWA3B | c.1205A>T p.Q402L | Missense Mutation (SNP) | VAF 68/147 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV101345924; called by muse, mutect2, varscan2
- WDR62 | c.4043C>T p.S1348F | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.541); catalogued as rs753208163, COSV54340520; called by muse, mutect2, varscan2
- ZFAT | c.1450G>T p.A484S | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.259); catalogued as COSV64749030; called by muse, mutect2
- ZNF292 | c.610C>T p.Q204* | Nonsense Mutation (SNP) | VAF 11/62 reads (18%) | catalogued as COSV100369667; called by muse, mutect2, varscan2
- ZNF568 | c.1733G>T p.R578I | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV61740747, COSV61743324; called by muse, mutect2
- ALB | c.1652+2del p.X551_splice | Splice Site (DEL) | VAF 8/48 reads (17%) | called by mutect2, pindel, varscan2
- GLRB | c.101dup p.K35Efs*23 | Frame Shift Ins (INS) | VAF 137/344 reads (40%) | called by mutect2, pindel, varscan2
- GPR174 | c.559_577del p.T187Gfs*3 | Frame Shift Del (DEL) | VAF 113/205 reads (55%) | called by mutect2, pindel, varscan2
- KIZ | c.1648del p.E550Kfs*18 | Frame Shift Del (DEL) | VAF 42/97 reads (43%) | called by pindel, varscan2
- TTN | c.42551_42553del p.E14184del (on ENST00000591111; = p.E6760del on NM_003319.4) | In Frame Del (DEL) | VAF 11/77 reads (14%) | called by mutect2, pindel, varscan2
- ACOT8 | c.225C>T p.V75= | Silent (SNP) | VAF 23/61 reads (38%) | catalogued as COSV99467222; called by muse, mutect2, varscan2
- ACSM5 | c.465G>A p.K155= | Silent (SNP) | VAF 17/91 reads (19%) | catalogued as rs755518647, COSV59375598; called by muse, mutect2, varscan2
- ANKRD1 | c.756A>C p.G252= | Silent (SNP) | VAF 14/65 reads (22%) | catalogued as COSV65468636; called by muse, mutect2, varscan2
- ARHGAP28 | c.1440C>A p.I480= (on ENST00000383472 / NM_001366230.1; = p.I321= on NM_001010000.3) | Silent (SNP) | VAF 24/53 reads (45%) | catalogued as COSV51648231; called by muse, mutect2, varscan2
- CALCOCO2 | c.400C>T p.L134= | Silent (SNP) | VAF 25/399 reads (6%) | catalogued as COSV99363616; called by muse, mutect2
- CFAP43 | c.207C>T p.G69= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as rs374123628; called by muse, mutect2, varscan2
- CNOT6L | c.768G>A p.E256= (on ENST00000504123 / NM_001286790.2; = p.E251= on NM_144571.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV53696949, COSV99361248; called by muse, mutect2, varscan2
- CSMD2 | c.561C>T p.A187= | Silent (SNP) | VAF 49/176 reads (28%) | catalogued as COSV53973776; called by muse, mutect2, varscan2
- DCAF5 | c.2373G>A p.E791= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV58463710; called by muse, mutect2, varscan2
- DOP1A | c.5643T>G p.V1881= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV52719855; called by muse, mutect2, varscan2
- ERAL1 | c.42G>C p.S14= | Silent (SNP) | VAF 71/161 reads (44%) | catalogued as COSV54741210; called by muse, mutect2, varscan2
- ETV1 | c.696C>T p.H232= | Silent (SNP) | VAF 153/373 reads (41%) | catalogued as rs577222571, COSV54136412; called by muse, mutect2, varscan2
- F9 | c.558T>A p.T186= | Silent (SNP) | VAF 86/199 reads (43%) | catalogued as COSV54380351, COSV54382823, COSV99496388; called by muse, mutect2, varscan2
- FAM47B | c.1275G>A p.P425= | Silent (SNP) | VAF 49/62 reads (79%) | catalogued as rs1343349349, COSV100264156, COSV61455837; called by muse, mutect2, varscan2
- FIBCD1 | c.870C>T p.D290= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as rs773144212, COSV99446653; called by muse, mutect2, varscan2
- LZTS1 | c.261C>T p.S87= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as rs1431971510, COSV56116423; called by muse, mutect2, varscan2
- NPM2 | c.84G>T p.R28= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as COSV57075841, COSV57076292; called by muse, mutect2, varscan2
- OR2F1 | c.21T>G p.T7= | Silent (SNP) | VAF 52/175 reads (30%) | catalogued as COSV67332199; called by muse, mutect2, varscan2
- P2RY13 | c.291T>C p.P97= | Silent (SNP) | VAF 36/173 reads (21%) | catalogued as COSV99851347; called by muse, mutect2, varscan2
- PCDH9 | c.3069T>C p.P1023= | Silent (SNP) | VAF 58/338 reads (17%) | catalogued as COSV60599278; called by muse, mutect2, varscan2
- PDLIM2 | c.171G>A p.A57= (on ENST00000397760; = p.A307= on NM_021630.6) | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as rs755738040, COSV56131999; called by muse, mutect2, varscan2
- PEAK3 | c.204G>A p.Q68= | Silent (SNP) | VAF 18/51 reads (35%) | catalogued as rs751201440, COSV59702731; called by muse, mutect2, varscan2
- PPL | c.4311C>T p.A1437= | Silent (SNP) | VAF 27/165 reads (16%) | catalogued as rs764049268, COSV99277381; called by muse, mutect2, varscan2
- PRDM11 | c.429G>A p.A143= (on ENST00000530656 / NM_001359633.1; = p.A109= on NM_001256695.1) | Silent (SNP) | VAF 8/48 reads (17%) | catalogued as rs143277934; called by muse, mutect2, varscan2
- RIMBP3 | c.2808C>T p.A936= | Silent (SNP) | VAF 16/152 reads (11%) | called by muse, mutect2
- RPTOR | c.3123C>T p.A1041= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs199631709, COSV60817688; called by muse, mutect2, varscan2
- SDK2 | c.1551C>T p.C517= | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as rs776557649, COSV101166632; called by muse, mutect2, varscan2
- SLC25A42 | c.537A>G p.R179= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as COSV59381985; called by muse, mutect2, varscan2
- THADA | c.2781A>C p.I927= | Silent (SNP) | VAF 42/115 reads (37%) | catalogued as COSV57695055; called by muse, mutect2, varscan2
- ZBTB16 | c.1773G>A p.T591= | Silent (SNP) | VAF 17/33 reads (52%) | catalogued as rs778496413, COSV60100853; called by muse, mutect2, varscan2
- ZNF30 | c.1869C>T p.P623= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as COSV57855621; called by muse, mutect2, varscan2
- AC244258.1 | n.311-5001G>C | Intron (SNP) | VAF 8/156 reads (5%) | called by muse, mutect2
- PCLO | c.14791+9C>T | Intron (SNP) | VAF 9/25 reads (36%) | catalogued as COSV61616495; called by muse, mutect2, varscan2
- PTGER3 | c.1077+85G>T | Intron (SNP) | VAF 25/99 reads (25%) | catalogued as COSV100138099; called by muse, mutect2, varscan2
- TTN | c.10360+1741G>T | Intron (SNP) | VAF 4/36 reads (11%) | catalogued as COSV100592313; called by muse, mutect2, varscan2
